Somatic mutation profile of tumor specimen TCGA-AJ-A3BI-01A (aliquot TCGA-AJ-A3BI-01A-11D-A20S-09) from TCGA case TCGA-AJ-A3BI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-AJ-A3BI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f448ce4-f582-46dd-be76-fc8804abf141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3BI-10A (Blood Derived Normal), aliquot TCGA-AJ-A3BI-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acff6b7f-4980-4d4f-a6d6-b79e4fc59751

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 26, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 22/26 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.209+1_209+2del p.X70_splice | Splice Site (DEL) | VAF 22/59 reads (37%) | hotspot (GDC flag); catalogued as rs1564826836; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.379G>T p.G127* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | hotspot (GDC flag); catalogued as rs587781255, CM128490, COSV64289445, COSV64291964; called by muse, mutect2, varscan2
- PTEN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.3073G>T p.V1025F | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99289284; called by muse, mutect2, varscan2
- ARHGAP36 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99358175; called by muse, mutect2, varscan2
- C3 | c.4456G>T p.E1486* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99837174; called by muse, mutect2, varscan2
- CDH23 | c.7462C>T p.R2488C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs909808363, COSV56471363; called by muse, mutect2, varscan2
- CYLC1 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.98); catalogued as COSV100255380; called by muse, mutect2, varscan2
- DIAPH2 | c.3155A>G p.E1052G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100235073; called by muse, mutect2, varscan2
- DNASE1L2 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV100066063; called by muse, mutect2, varscan2
- GRM7 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100738313; called by muse, mutect2
- HELZ2 | c.5110G>C p.D1704H (on ENST00000467148 / NM_001037335.2; = p.D1135H on NM_033405.3) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs758737285, COSV101427612, COSV71297181; called by muse, mutect2, varscan2
- KIAA1217 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs371753454; called by muse, mutect2, varscan2
- KLHL20 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV52942537, COSV99268650; called by muse, mutect2, varscan2
- LPA | c.4210A>G p.I1404V | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1255326656, COSV60304975; called by muse, mutect2, varscan2
- NAV2 | c.5089C>T p.R1697W (on ENST00000396087 / NM_001244963.2; = p.R1641W on NM_145117.5) | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs151080998, COSV100216568; called by muse, mutect2, varscan2
- NFATC1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs769706337, COSV99502444; called by muse, varscan2
- OR4C13 | c.797A>T p.D266V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101634233; called by muse, mutect2, varscan2
- PDE4DIP | c.6407C>G p.P2136R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.817); catalogued as COSV100521526; called by mutect2, varscan2
- PLEKHM3 | c.1855C>G p.R619G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101216846, COSV66817608; called by muse, mutect2, varscan2
- PLK4 | c.339T>G p.A113= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99584929; called by muse, mutect2, varscan2
- PPP1R3A | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99493181, COSV99494112; called by muse, mutect2, varscan2
- PRKAG3 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs570196271, COSV99291927; called by muse, mutect2, varscan2
- PSMD1 | c.1651G>C p.G551R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100433869; called by muse, mutect2, varscan2
- REC8 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV100269219, COSV100269261; called by muse, mutect2, varscan2
- SMG1 | c.10093C>T p.P3365S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101246749; called by muse, varscan2
- SNAP91 | c.1706A>G p.E569G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99536420; called by muse, mutect2, varscan2
- TCERG1 | c.2086C>T p.L696F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99695242; called by muse, mutect2, varscan2
- WDFY3 | c.6097A>G p.T2033A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99885430; called by muse, mutect2, varscan2
- ZRSR2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 49/66 reads (74%) | catalogued as COSV100315328, COSV57065798; called by muse, mutect2, varscan2
- MARCHF1 | c.687_694del p.K230Qfs*23 (on ENST00000274056; = p.K213Qfs*23 on NM_017923.4) | Frame Shift Del (DEL) | VAF 20/36 reads (56%) | called by mutect2, pindel, varscan2
- TP53 | c.595_598del p.G199Ifs*47 | Frame Shift Del (DEL) | VAF 27/35 reads (77%) | called by pindel, varscan2
- BOD1L1 | c.1926C>T p.D642= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs746388425, COSV99240272; called by muse, mutect2
- CCDC40 | c.2562G>A p.S854= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as rs760217617, COSV100884316; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCN | c.39T>C p.V13= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99272665; called by muse, mutect2, varscan2
- GRM8 | c.1686C>G p.P562= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100285649, COSV58824465; called by muse, mutect2, varscan2
- KLHL8 | c.1110A>C p.A370= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs750256475, COSV99911564; called by muse, mutect2, varscan2
- PCDH15 | c.1383C>T p.R461= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100226899; called by muse, mutect2, varscan2
- RELN | c.2484A>T p.L828= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100634803; called by muse, mutect2, varscan2
- SEPTIN6 | c.94C>T p.L32= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100595774; called by muse, varscan2
